Somatic mutation profile of tumor specimen TCGA-BT-A20O-01A (aliquot TCGA-BT-A20O-01A-21D-A14W-08) from TCGA case TCGA-BT-A20O, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 75.4 years (27,534 days).
Specimen TCGA-BT-A20O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86e91d78-4a7d-428f-b9ae-af9a970b6ef7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BT-A20O-11A (Solid Tissue Normal), aliquot TCGA-BT-A20O-11A-11D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d36315ff-3318-45d8-a0c7-cae5aea069b4

The open-access MAF lists 169 somatic variants for this specimen: 131 protein-altering or splice-affecting, 34 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 116, Silent 34, Nonsense Mutation 10, Frame Shift Del 3, 5'UTR 2, Splice Region 1, Frame Shift Ins 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1436G>C p.R479P (on ENST00000281708 / NM_001349798.2; = p.R399P on NM_018315.5) | Missense Mutation (SNP) | VAF 5/67 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, mutect2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 8/49 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.1481C>A p.A494D | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52223614; called by muse, mutect2
- ABCA9 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV60626029; called by muse, mutect2, varscan2
- AC004593.2 | c.1028T>C p.L343P | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.074); catalogued as COSV56093655; called by muse, mutect2, varscan2
- ACTA2 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.791); catalogued as COSV56516855; called by muse, mutect2
- ADGRF5 | c.773C>T p.T258I | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.975); catalogued as COSV51935023; called by muse, mutect2
- AHNAK2 | c.13274C>T p.S4425F | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60917744; called by muse, mutect2
- AK9 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); catalogued as COSV53421610; called by muse, mutect2, varscan2
- AOPEP | c.2101G>C p.E701Q (on ENST00000375315 / NM_001193329.1; = p.E602Q on NM_032823.5) | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1171949519, COSV52991604, COSV52997289, COSV99951066; called by muse, mutect2, varscan2
- APOL1 | c.899C>T p.S300L | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.22); catalogued as COSV59869182; called by muse, mutect2, varscan2
- ARCN1 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.762); catalogued as COSV50615404; called by muse, mutect2
- ARHGAP30 | c.1985A>G p.Q662R | Missense Mutation (SNP) | VAF 27/176 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV63517004; called by muse, mutect2, varscan2
- ARHGAP36 | c.1169A>T p.K390I | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as COSV52266389, COSV52267715; called by muse, mutect2
- ARID5B | c.1193A>G p.Y398C | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54421968; called by muse, mutect2
- ASH1L | c.2994G>C p.L998F | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.881); catalogued as COSV64208900; called by muse, mutect2
- ASIC1 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV57320159; called by muse, mutect2
- ATPAF2 | c.763C>T p.H255Y | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58263971; called by muse, mutect2
- ATRNL1 | c.4127G>A p.G1376E | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100370145, COSV58092217; called by muse, mutect2, varscan2
- BDKRB1 | c.132C>G p.I44M | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.338); catalogued as COSV53706101, COSV53706421; called by muse, mutect2
- C1orf146 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV64860557; called by muse, mutect2, varscan2
- CASP5 | c.1135T>G p.F379V | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52829091; called by muse, mutect2, varscan2
- CASP8 | c.29T>C p.I10T | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51852343; called by muse, mutect2
- CELSR1 | c.9019G>A p.D3007N | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs748964134; called by muse, mutect2, varscan2
- CFAP43 | c.1372G>A p.V458I | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as rs753365408, COSV53376338; called by muse, mutect2, varscan2
- CLDN2 | c.468G>A p.M156I | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.622); catalogued as COSV61020890, COSV61021417; called by muse, mutect2, varscan2
- COQ8A | c.1699G>T p.G567W | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62012497; called by muse, mutect2, varscan2
- CORO2B | c.187G>A p.G63S | Missense Mutation (SNP) | VAF 4/83 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1410563970, COSV55951812; called by muse, mutect2
- CORO2B | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 4/81 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55952983, COSV99963528; called by muse, mutect2
- CREBBP | c.3221C>G p.S1074* | Nonsense Mutation (SNP) | VAF 13/174 reads (7%) | catalogued as COSV99270932; called by muse, mutect2
- CUL4B | c.218G>A p.R73K | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV60688147, COSV60690951; called by mutect2, varscan2
- CUX1 | c.2662C>G p.P888A | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.292); catalogued as rs1554519947, COSV52902303, COSV99471073; called by muse, mutect2, varscan2
- DARS1 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV51538914; called by muse, mutect2
- DNAH3 | c.7063G>C p.D2355H | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54507074, COSV54526902; called by muse, mutect2
- EGFL7 | c.122C>G p.S41C | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as COSV58247885; called by muse, mutect2, varscan2
- EIF3I | c.230G>C p.R77P | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as COSV100557182, COSV59084526; called by muse, mutect2
- EIF4G3 | c.1892A>G p.D631G | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs764709894, COSV51684221; called by muse, mutect2
- ERCC2 | c.1975C>T p.H659Y | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV67266544; called by muse, varscan2
- ERG | c.1153A>G p.M385V (on ENST00000398919 / NM_001243428.1; = p.M361V on NM_004449.4) | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55733398; called by muse, mutect2, varscan2
- ETV6 | c.1039C>T p.Q347* | Nonsense Mutation (SNP) | VAF 17/179 reads (9%) | catalogued as COSV56765865, COSV56766513; called by muse, mutect2
- EWSR1 | c.1687C>T p.R563C | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs199957418, COSV58424345; called by mutect2, varscan2
- FCGBP | c.6535G>T p.V2179L | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.295); catalogued as COSV55440303; called by muse, mutect2
- FMO4 | c.1081G>C p.E361Q | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.082); catalogued as COSV63001283; called by muse, mutect2, varscan2
- FTSJ3 | c.2221A>G p.K741E | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV63790325; called by muse, mutect2
- GAB4 | c.1193C>G p.S398C | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.087); catalogued as COSV68754028; called by muse, mutect2, varscan2
- GARRE1 | c.2101C>T p.R701W | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.653); catalogued as rs144261536; called by muse, mutect2
- GATAD2B | c.392A>G p.N131S | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.935); catalogued as rs1430189525, COSV64084453; called by muse, mutect2, varscan2
- GET4 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV56254991; called by muse, mutect2, varscan2
- GPLD1 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.418); catalogued as COSV57758110; called by muse, mutect2, varscan2
- GRM4 | c.1971C>G p.I657M | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as COSV65214339; called by muse, mutect2, varscan2
- GUCY1B1 | c.565G>C p.E189Q | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV52375244; called by muse, mutect2
- HCFC1 | c.1123G>A p.A375T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV60074912; called by muse, mutect2
- HNRNPA3 | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 10/143 reads (7%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.994); catalogued as COSV66820862; called by muse, mutect2
- HSP90B1 | c.1637G>C p.R546T | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.972); catalogued as COSV55355860; called by muse, mutect2
- HSPBAP1 | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV60242569; called by muse, mutect2
- IGLV11-55 | c.223T>G p.S75A | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV66504538; called by muse, mutect2
- IHO1 | c.1747G>A p.D583N | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); catalogued as COSV56508112; called by muse, mutect2
- IL1RAPL2 | c.393G>C p.L131F | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV61161573; called by mutect2, varscan2
- INTS1 | c.5828T>C p.L1943P | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.081); catalogued as COSV67177877; called by muse, mutect2, varscan2
- KCNH6 | c.2845C>G p.L949V | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV59000340, COSV59000795, COSV59004189; called by muse, mutect2
- KCNJ15 | c.223G>A p.V75M | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as rs1227840730, COSV60811113; called by muse, mutect2
- KDM3B | c.3749A>G p.E1250G | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV58691298; called by muse, mutect2, varscan2
- KRT31 | c.320T>A p.F107Y | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.139); catalogued as COSV52436028, COSV99289929; called by mutect2, varscan2
- LAX1 | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV65849523; called by mutect2, varscan2
- LRP2 | c.12448G>T p.D4150Y | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV55557106; called by muse, mutect2
- LTBP2 | c.3859C>G p.L1287V | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.422); catalogued as COSV56209244, COSV56213104; called by muse, mutect2, varscan2
- MAP7D1 | c.165G>T p.M55I | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.05); catalogued as COSV60216719; called by muse, mutect2
- MMP16 | c.340C>T p.H114Y | Missense Mutation (SNP) | VAF 10/185 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV54150706, COSV54169162; called by muse, mutect2
- MYO9B | c.955C>G p.L319V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV68279786; called by muse, mutect2, varscan2
- NF2 | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as CD962104, COSV58521298, COSV58524898; called by muse, mutect2
- NID2 | c.3352A>G p.I1118V | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV53497500; called by muse, varscan2
- NOP14 | c.1336G>C p.E446Q | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.027); catalogued as rs746129234, COSV58625714; called by muse, mutect2, varscan2
- NTNG1 | c.1045G>C p.G349R | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53973918; called by muse, mutect2
- OR51S1 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as COSV59058489; called by muse, mutect2
- PKHD1L1 | c.5416C>T p.P1806S | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as rs769479999, COSV65744726; called by muse, mutect2
- PLCXD2 | c.151C>G p.L51V | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV67340413; called by muse, mutect2
- PLXNB2 | c.4197G>T p.R1399S | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV63782272; called by muse, mutect2, varscan2
- PRPF31 | c.1309G>C p.G437R | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100320033; called by muse, mutect2
- PRPF31 | c.1310G>C p.G437A | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs776053848, COSV100320034; called by muse, mutect2
- PTGIR | c.797C>G p.P266R | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.908); catalogued as COSV52192367; called by muse, mutect2, varscan2
- PTPRH | c.3040G>A p.G1014S | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1211645314; called by muse, mutect2
- RIPPLY1 | c.314C>T p.S105F | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as COSV52174133; called by muse, mutect2
- RIT2 | c.590G>C p.R197T | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as rs77976328, COSV58667311; called by muse, mutect2, varscan2
- RUSC2 | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs758569757, COSV63427619; called by muse, mutect2, varscan2
- RYR2 | c.4304G>A p.G1435E | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as COSV63689756; called by muse, mutect2, varscan2
- SCP2 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as COSV65261334; called by muse, mutect2
- SLC26A9 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.216); catalogued as COSV100536564; called by muse, mutect2
- SMG1 | c.5720C>T p.S1907F | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as COSV67171967; called by muse, mutect2, varscan2
- SMPD1 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.43); catalogued as CM130679, COSV54970807; called by muse, mutect2
- SORCS3 | c.2738C>A p.P913H | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV63795587; called by muse, mutect2
- SP2 | c.1136C>T p.T379I | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV65064303; called by muse, mutect2, varscan2
- STXBP3 | c.1471G>A p.D491N | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.717); catalogued as COSV64182403, COSV64184047; called by muse, mutect2, varscan2
- TASOR2 | c.109C>G p.L37V | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60167836; called by muse, mutect2, varscan2
- TCF20 | c.1679C>T p.P560L | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs758708684, COSV59492177; called by muse, mutect2, varscan2
- TEAD3 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV58817057; called by muse, mutect2, varscan2
- TENM1 | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV64433794; called by muse, mutect2, varscan2
- THSD7B | c.3229G>C p.E1077Q (on ENST00000272643; = p.E1075Q on NM_001316349.2) | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.997); catalogued as rs1426592030, COSV55695788, COSV55697761; called by muse, mutect2, varscan2
- TLCD3A | c.252G>A p.M84I | Missense Mutation (SNP) | VAF 15/195 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.266); catalogued as rs143392294; called by muse, mutect2
- TM7SF2 | c.1171G>C p.E391Q | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV54205001; called by muse, mutect2
- TNNI2 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.48); catalogued as COSV53289983; called by muse, mutect2, varscan2
- TP53 | c.835G>C p.G279R | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM137622, COSV52705216, COSV52823842, COSV53165376, COSV53486085; called by muse, mutect2
- TRAPPC8 | c.329G>A p.G110E | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as rs1196790137, COSV51972167; called by muse, mutect2
- TSPAN3 | c.571G>T p.D191Y | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.55); catalogued as COSV51215007; called by muse, mutect2, varscan2
- TSPYL1 | c.793C>G p.L265V | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.587); catalogued as COSV63994111; called by muse, mutect2
- VWA8 | c.2030T>G p.L677R | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV55697791; called by muse, mutect2
- XRCC1 | c.52A>G p.T18A | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as rs1340233641, COSV53450332; called by muse, mutect2, varscan2
- ZFHX3 | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT tolerated, low confidence (0.47); PolyPhen possibly damaging (0.543); catalogued as rs1031053699, COSV51721354; called by muse, mutect2, varscan2
- ZNF283 | c.1496G>C p.G499A | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.018); catalogued as COSV61031529; called by muse, varscan2
- ZNF536 | c.3227C>G p.S1076C | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.417); catalogued as COSV62825810; called by muse, mutect2, varscan2
- ABCA8 | c.151C>T p.H51Y | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.425); called by muse, mutect2
- AC013489.1 | c.431G>T p.C144F | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.8); called by muse, mutect2
- ARID1A | c.5441_5442dup p.K1815* | Frame Shift Ins (INS) | VAF 10/61 reads (16%) | called by mutect2, varscan2
- CAMTA1 | c.1588A>T p.K530* | Nonsense Mutation (SNP) | VAF 6/69 reads (9%) | called by muse, mutect2
- CAPN13 | c.1146del p.N383Mfs*15 | Frame Shift Del (DEL) | VAF 7/51 reads (14%) | called by mutect2, pindel, varscan2
- CATSPERD | c.1895C>A p.T632N | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); called by muse, mutect2
- CENPL | c.4_16del p.D2Hfs*17 | Frame Shift Del (DEL) | VAF 12/86 reads (14%) | called by mutect2, pindel
- DLX3 | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- FAT1 | c.6086C>A p.S2029* | Nonsense Mutation (SNP) | VAF 26/266 reads (10%) | called by muse, mutect2
- FAT3 | c.2172T>G p.Y724* | Nonsense Mutation (SNP) | VAF 22/190 reads (12%) | called by muse, mutect2, varscan2
- GIT1 | c.380G>A p.G127E | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.027); called by muse, mutect2
- GLT1D1 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- HIVEP1 | c.5080C>T p.Q1694* | Nonsense Mutation (SNP) | VAF 17/119 reads (14%) | called by muse, mutect2, varscan2
- IGBP1P2 | c.905A>G p.Q302R | Missense Mutation (SNP) | VAF 31/460 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.019); called by muse, mutect2
- IQCC | c.1121T>A p.L374* | Nonsense Mutation (SNP) | VAF 14/159 reads (9%) | called by muse, mutect2
- LMO2 | c.99C>A p.C33* (on ENST00000395833 / NM_001142315.2; = p.C102* on NM_005574.4) | Nonsense Mutation (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2, varscan2
- LYST | c.2089C>T p.Q697* | Nonsense Mutation (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2, varscan2
- NBPF11 | c.1002C>A p.C334* | Nonsense Mutation (SNP) | VAF 10/304 reads (3%) | called by muse, mutect2
- NBPF11 | c.1001G>A p.C334Y | Missense Mutation (SNP) | VAF 10/301 reads (3%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.982); called by muse, mutect2
- SLC35E2A | n.1002G>T | Splice Region (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2, varscan2
- TAF4B | c.527_537del p.T176Kfs*57 | Frame Shift Del (DEL) | VAF 8/77 reads (10%) | called by mutect2, pindel
- ZZEF1 | c.997G>C p.D333H | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- AHNAK2 | c.13533C>A p.L4511= | Silent (SNP) | VAF 27/190 reads (14%) | catalogued as COSV60917735; called by muse, mutect2, varscan2
- ALDH16A1 | c.1453C>T p.L485= | Silent (SNP) | VAF 10/172 reads (6%) | catalogued as COSV53194491; called by muse, mutect2
- AP3B2 | c.1596A>G p.A532= | Silent (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- CDC42BPA | c.3102G>C p.V1034= (on ENST00000334218 / NM_001366019.2; = p.V1021= on NM_003607.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV62012502; called by muse, mutect2, varscan2
- CIT | c.3517C>T p.L1173= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as COSV55871450; called by muse, mutect2, varscan2
- DEUP1 | c.492G>C p.L164= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV53212895; called by muse, mutect2, varscan2
- DOCK8 | c.4896G>A p.K1632= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV66620695; called by muse, mutect2, varscan2
- DST | c.16053G>A p.Q5351= (on ENST00000361203 / NM_001374722.1; = p.Q2939= on NM_015548.5) | Silent (SNP) | VAF 5/73 reads (7%) | catalogued as COSV55019167; called by muse, mutect2
- EIF4G2 | c.1995A>G p.L665= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as rs140144694; called by muse, mutect2, varscan2
- FAM83F | c.579C>T p.Y193= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as rs1286082216, COSV61000396; called by muse, mutect2, varscan2
- FOXK2 | c.798G>C p.L266= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV58879637; called by muse, mutect2, varscan2
- FRA10AC1 | c.261C>T p.Y87= | Silent (SNP) | VAF 18/237 reads (8%) | catalogued as COSV63272443; called by muse, mutect2
- KCNAB1 | c.873C>T p.G291= (on ENST00000490337 / NM_172160.3; = p.G280= on NM_003471.3) | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as rs1214474625, COSV56746708; called by muse, mutect2, varscan2
- KRBA2 | c.930A>G p.L310= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV58779155; called by muse, mutect2, varscan2
- LGR5 | c.1998G>A p.V666= | Silent (SNP) | VAF 15/169 reads (9%) | catalogued as rs1203294355, COSV57005675; called by muse, mutect2
- MAGI3 | c.2724G>C p.G908= | Silent (SNP) | VAF 11/107 reads (10%) | catalogued as COSV56837211; called by muse, mutect2, varscan2
- MOGAT2 | c.558G>A p.G186= | Silent (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- NAXE | c.819G>A p.L273= | Silent (SNP) | VAF 11/137 reads (8%) | catalogued as COSV58040361; called by muse, mutect2
- PCDHB2 | c.1458C>G p.A486= | Silent (SNP) | VAF 13/186 reads (7%) | called by muse, mutect2
- PEAK1 | c.1839G>A p.E613= | Silent (SNP) | VAF 14/173 reads (8%) | catalogued as COSV56932486; called by muse, mutect2
- RASGRF2 | c.1749C>A p.I583= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV54131356; called by muse, mutect2, varscan2
- SEC61A2 | c.1182G>T p.L394= | Silent (SNP) | VAF 17/248 reads (7%) | catalogued as COSV53652638; called by muse, mutect2
- SLC12A2 | c.1899C>T p.N633= | Silent (SNP) | VAF 11/132 reads (8%) | catalogued as COSV52472193; called by muse, mutect2
- SLC26A9 | c.162G>T p.G54= | Silent (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2
- SLC30A9 | c.1191T>C p.D397= | Silent (SNP) | VAF 6/136 reads (4%) | catalogued as COSV52556615; called by muse, mutect2
- SLC4A8 | c.2973C>G p.V991= | Silent (SNP) | VAF 7/93 reads (8%) | catalogued as COSV60653606; called by muse, mutect2
- STH | c.141C>A p.T47= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV52241272; called by muse, mutect2, varscan2
- TDRD7 | c.3022C>T p.L1008= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as COSV62429768; called by muse, mutect2
- TRIM71 | c.1116G>A p.K372= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV67471328; called by muse, mutect2, varscan2
- UGT2B10 | c.1084C>T p.L362= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV55321078; called by muse, mutect2
- ZEB2 | c.3147C>T p.H1049= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV57958188; called by muse, mutect2, varscan2
- ZNF346 | c.270A>T p.A90= | Silent (SNP) | VAF 12/128 reads (9%) | catalogued as COSV56156792; called by muse, mutect2
- ZNF385A | c.465G>A p.E155= (on ENST00000338010 / NM_001130967.3; = p.E135= on NM_015481.3) | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as COSV61493562, COSV61494673; called by muse, mutect2, varscan2
- ZNF468 | c.51C>T p.F17= | Silent (SNP) | VAF 8/180 reads (4%) | catalogued as COSV54695117, COSV54696011, COSV99700817; called by muse, mutect2
- ATP2B2 | c.*54G>A | 3'UTR (SNP) | VAF 4/66 reads (6%) | catalogued as COSV59503234; called by muse, mutect2
- C5orf58 | c.-21G>A | 5'UTR (SNP) | VAF 3/33 reads (9%) | catalogued as COSV69758890; called by muse, mutect2
- HK1 | chr10:69315999 G>A | 5'Flank (SNP) | VAF 9/129 reads (7%) | catalogued as rs1429760292, COSV53859552; called by muse, mutect2
- PHC3 | c.-5C>T | 5'UTR (SNP) | VAF 14/241 reads (6%) | catalogued as COSV71923549; called by muse, mutect2
